Somatic mutation profile of tumor specimen MMRF_2792_1_BM_CD138pos (aliquot MMRF_2792_1_BM_CD138pos_T1_KHS5U_L15733) from MMRF case MMRF_2792, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.3 years (22,024 days).
Specimen MMRF_2792_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e551567c-c174-4849-9a4e-1a310ed35c7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2792_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2792_1_PB_WBC_C2_KHS5U_L15777; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffd7bab4-ef50-437a-b736-046463379daa

The open-access MAF lists 123 somatic variants for this specimen: 63 protein-altering or splice-affecting, 11 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 28, Silent 11, RNA 8, 5'UTR 5, Intron 4, Frame Shift Del 3, 5'Flank 2, 3'Flank 2, Splice Region 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 77/209 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 184/384 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANGPTL5 | c.539A>T p.E180V | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100527724; called by muse, mutect2, varscan2
- AP2B1 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs1337313119; called by muse, mutect2
- BTBD10 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.446); catalogued as rs1216227218, COSV53400185; called by muse, mutect2
- DCT | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV65469118, COSV65469255; called by muse, mutect2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2, varscan2
- F9 | c.1350del p.Y450* | Frame Shift Del (DEL) | VAF 31/159 reads (19%) | catalogued as CM125302; called by mutect2, pindel, varscan2
- FNDC7 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.371); catalogued as rs377221440, COSV54757258; called by muse, mutect2, varscan2
- H1-3 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.345); catalogued as rs1270956258, COSV55097425; called by muse, mutect2
- IGLL5 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.119); catalogued as rs201857114, COSV66537362; called by muse, varscan2
- MAGEA8 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs143187496, COSV54063868; called by muse, mutect2, varscan2
- PCDHGB3 | c.2338C>A p.L780I | Missense Mutation (SNP) | VAF 143/274 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as rs756612454; called by muse, mutect2, varscan2
- PRPS1L1 | c.410T>C p.F137S | Missense Mutation (SNP) | VAF 9/260 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1213066296; called by muse, mutect2
- SALL2 | c.1202A>T p.Y401F | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.96); catalogued as COSV58101922; called by muse, varscan2
- SDK1 | c.2648C>G p.S883C | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1312883276, COSV67372908; called by muse, mutect2, varscan2
- SLC5A10 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs773745208; called by muse, mutect2, varscan2
- SMARCA2 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100571492, COSV61804522; called by muse, mutect2, varscan2
- SPEF2 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs573848490, COSV56801103; called by muse, mutect2, varscan2
- SPTBN5 | c.1741C>G p.Q581E | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs1450774661; called by muse, mutect2, varscan2
- ZNF572 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476717855, COSV100073952; called by muse, mutect2
- ACOX3 | c.1210G>C p.A404P | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ACTB | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AJAP1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANP32E | c.215G>C p.S72T | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- ATP8B4 | c.913C>G p.Q305E | Missense Mutation (SNP) | VAF 97/196 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- C6orf120 | c.233T>A p.L78Q | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CLDND2 | c.377del p.F126Sfs*27 | Frame Shift Del (DEL) | VAF 64/178 reads (36%) | called by mutect2, pindel, varscan2
- COL12A1 | c.7330G>A p.A2444T | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- COL4A5 | c.3529C>T p.P1177S | Missense Mutation (SNP) | VAF 96/100 reads (96%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, varscan2
- CSMD3 | c.10506A>C p.K3502N (on ENST00000297405 / NM_001363185.1; = p.K3333N on NM_052900.3) | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- CTAGE1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.262); called by muse, mutect2
- DLC1 | c.3828G>A p.M1276I (on ENST00000276297 / NM_001348081.2; = p.M839I on NM_006094.5) | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- DNAH6 | c.3475G>A p.G1159R | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DNAH7 | c.6992A>G p.K2331R | Missense Mutation (SNP) | VAF 9/223 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.346); called by muse, mutect2
- DTX1 | c.622G>C p.V208L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- EPHA5 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FKBP11 | c.196-5C>T | Splice Region (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- FOXA1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GLDN | c.178C>A p.R60S | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HNRNPC | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HSPA9 | c.1639A>T p.I547F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LINC02453 | n.127T>C | Splice Region (SNP) | VAF 42/94 reads (45%) | called by muse, mutect2, varscan2
- MAP2K5 | c.667T>C p.Y223H | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2
- OR13C2 | c.486dup p.V163Cfs*10 | Frame Shift Ins (INS) | VAF 130/624 reads (21%) | called by mutect2, varscan2
- PDZD3 | c.1138G>T p.V380L (on ENST00000531114; = p.V300L on NM_024791.4) | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PIP | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PLEKHG4 | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPN7 | c.402C>A p.S134R (on ENST00000495688; = p.S173R on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRF | c.2728A>T p.T910S | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2
- RFX6 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 140/328 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- RFXAP | c.539A>C p.D180A | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ROBO3 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 23/327 reads (7%) | called by muse, mutect2
- RYR3 | c.1547T>G p.I516S | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SEC11A | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by mutect2, varscan2
- SPEG | c.916T>A p.S306T | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- STK10 | c.2767-8_2767-1del p.X923_splice | Splice Site (DEL) | VAF 61/150 reads (41%) | called by mutect2, pindel, varscan2
- TGFBR3 | c.1811del p.L604Wfs*63 | Frame Shift Del (DEL) | VAF 39/98 reads (40%) | called by mutect2, pindel, varscan2
- USP25 | c.966G>C p.Q322H | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- YES1 | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- YTHDC2 | c.424A>T p.T142S | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- ZC3H4 | c.795C>G p.S265R | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZP4 | c.371A>C p.K124T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CCDC105 | c.1248A>C p.A416= | Silent (SNP) | VAF 31/142 reads (22%) | called by muse, mutect2, varscan2
- CCKAR | c.999C>T p.N333= | Silent (SNP) | VAF 125/280 reads (45%) | catalogued as rs199510290, COSV55162310; called by muse, mutect2, varscan2
- CRPPA | c.945C>T p.V315= (on ENST00000407010 / NM_001368197.1; = p.V265= on NM_001101417.4) | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs1554300356; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR20 | c.213C>T p.N71= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as rs1439261681, COSV66684258; called by muse, mutect2
- JPH2 | c.705G>A p.S235= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV100881801; called by muse, mutect2
- OLFML2B | c.417G>A p.E139= | Silent (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- PAX7 | c.1245G>T p.S415= | Silent (SNP) | VAF 50/90 reads (56%) | catalogued as COSV64749322; called by muse, mutect2, varscan2
- PDILT | c.1008C>T p.V336= | Silent (SNP) | VAF 7/182 reads (4%) | called by muse, mutect2
- PLA2G2C | c.204C>G p.P68= | Silent (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.2415G>A p.G805= | Silent (SNP) | VAF 37/137 reads (27%) | called by muse, mutect2, varscan2
- ZIC1 | c.636C>T p.A212= | Silent (SNP) | VAF 61/342 reads (18%) | catalogued as COSV51550289; called by muse, mutect2, varscan2
- AC092070.2 | n.2261G>C | RNA (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- ACER1 | c.*125C>A | 3'UTR (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- AK9 | c.3633+727G>T | Intron (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- AL354707.1 | n.1412A>G | RNA (SNP) | VAF 52/106 reads (49%) | catalogued as rs373502990; called by muse, mutect2, varscan2
- AL359195.2 | n.3622C>T | RNA (SNP) | VAF 74/202 reads (37%) | called by muse, mutect2
- ANO5 | c.*2081G>A | 3'UTR (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- BCAT1 | chr12:24949301 A>G | 5'Flank (SNP) | VAF 18/326 reads (6%) | called by muse, mutect2
- C12orf77 | n.281A>C | RNA (SNP) | VAF 137/363 reads (38%) | called by muse, mutect2, varscan2
- CCL18 | c.*677A>G | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- CHODL | c.79+582G>T | Intron (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- CT867976.1 | n.2460A>T | RNA (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- EIF4A2 | c.*466T>G | 3'UTR (SNP) | VAF 14/331 reads (4%) | called by muse, mutect2
- EYS | c.1766+5312T>G | Intron (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2
- FAM122A | c.*2037C>G | 3'UTR (SNP) | VAF 75/173 reads (43%) | called by muse, mutect2, varscan2
- FCGR2A | c.*292T>A | 3'UTR (SNP) | VAF 190/760 reads (25%) | called by muse, varscan2
- FGFRL1 | c.-26A>G | 5'UTR (SNP) | VAF 104/247 reads (42%) | catalogued as rs752839886; called by muse, mutect2, varscan2
- GOLM1 | c.-13C>T | 5'UTR (SNP) | VAF 134/312 reads (43%) | catalogued as rs764908240; called by muse, mutect2, varscan2
- GRID1 | c.*854G>A | 3'UTR (SNP) | VAF 113/236 reads (48%) | called by muse, mutect2, varscan2
- HEPACAM | c.*296T>G | 3'UTR (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2
- IGHV1-46 | c.-57T>C | 5'UTR (SNP) | VAF 37/37 reads (100%) | called by muse, varscan2
- IGLL5 | c.*164C>G | 3'UTR (SNP) | VAF 135/286 reads (47%) | called by muse, mutect2, varscan2
- ISX | c.-237G>C | 5'UTR (SNP) | VAF 160/368 reads (43%) | called by muse, mutect2, varscan2
- KIF3C | c.*738A>G | 3'UTR (SNP) | VAF 51/113 reads (45%) | called by muse, mutect2, varscan2
- LILRB4 | chr19:54668808 T>A | 3'Flank (SNP) | VAF 52/106 reads (49%) | called by muse, mutect2, varscan2
- LINC01556 | n.311G>T | RNA (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- MAK16 | c.*481del | 3'UTR (DEL) | VAF 93/212 reads (44%) | called by mutect2, pindel, varscan2
- MAP9 | c.*3050A>C | 3'UTR (SNP) | VAF 47/86 reads (55%) | called by muse, mutect2, varscan2
- MAVS | c.*2503G>A | 3'UTR (SNP) | VAF 18/65 reads (28%) | catalogued as rs1423092693; called by muse, mutect2, varscan2
- MRAS | c.*2949G>A | 3'UTR (SNP) | VAF 11/330 reads (3%) | called by muse, mutect2
- NFE2L2 | chr2:177264812 C>G | 5'Flank (SNP) | VAF 18/30 reads (60%) | called by muse, mutect2, varscan2
- NLGN1 | c.*1331T>C | 3'UTR (SNP) | VAF 14/152 reads (9%) | catalogued as rs916697089; called by muse, mutect2
- NR6A1 | c.*4251C>T | 3'UTR (SNP) | VAF 45/104 reads (43%) | catalogued as rs1192948147; called by muse, mutect2, varscan2
- NRG3 | chr10:82986475 T>G | 3'Flank (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- OR51F5P | n.467C>G | RNA (SNP) | VAF 95/198 reads (48%) | catalogued as rs139375941; called by muse, mutect2, varscan2
- PAK2 | c.*1858C>T | 3'UTR (SNP) | VAF 12/229 reads (5%) | called by muse, mutect2
- PARP8 | c.*3060G>A | 3'UTR (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- PEX26 | c.*2292C>A | 3'UTR (SNP) | VAF 102/203 reads (50%) | called by muse, mutect2, varscan2
- PI15 | c.-40-53C>A | Intron (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99477825; called by muse, mutect2, varscan2
- PLAU | c.*706T>C | 3'UTR (SNP) | VAF 31/110 reads (28%) | called by muse, mutect2, varscan2
- PTPRD | c.*2232A>T | 3'UTR (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.*997A>T | 3'UTR (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- SLC16A7 | c.*1623T>C | 3'UTR (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- SLC22A15 | c.*2260G>C | 3'UTR (SNP) | VAF 31/107 reads (29%) | catalogued as rs1026647240; called by muse, mutect2, varscan2
- SUB1 | c.*955G>C | 3'UTR (SNP) | VAF 92/497 reads (19%) | called by muse, mutect2, varscan2
- TMEM209 | c.*680T>C | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- TMPRSS11A | c.-322T>C | 5'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2
- TNFSF8 | c.*782A>G | 3'UTR (SNP) | VAF 84/182 reads (46%) | called by muse, mutect2
- TYRL | n.406G>T | RNA (SNP) | VAF 77/202 reads (38%) | called by muse, mutect2, varscan2
- UEVLD | c.*748G>A | 3'UTR (SNP) | VAF 27/48 reads (56%) | called by muse, mutect2, varscan2
